Somatic mutation profile of tumor specimen TCGA-B5-A11Z-01A (aliquot TCGA-B5-A11Z-01A-11D-A10M-09) from TCGA case TCGA-B5-A11Z, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 61.6 years (22,505 days).
Specimen TCGA-B5-A11Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce375816-f5b8-4c6d-b3f0-227e8d1ca387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11Z-10A (Blood Derived Normal), aliquot TCGA-B5-A11Z-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dd676e3-e737-4c2b-ad15-f0f24e1dd0d4

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 17, Nonsense Mutation 2, In Frame Ins 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 21/47 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.4537C>T p.Q1513* | Nonsense Mutation (SNP) | VAF 50/102 reads (49%) | catalogued as rs929311433, COSV55435848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 52/65 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD16B | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs767286554, COSV53862205; called by muse, mutect2, varscan2
- AFG3L2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs774586707, COSV52314007; called by muse, mutect2, varscan2
- ARHGAP33 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs748846672, COSV50119943, COSV50121836; called by muse, mutect2, varscan2
- B3GNT9 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs1024391038, COSV54626847; called by muse, mutect2, varscan2
- BAHD1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs758192890, COSV69083789; called by muse, mutect2, varscan2
- BTN2A2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs747698008, COSV61857114; called by muse, mutect2
- CABYR | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV59110743; called by muse, mutect2, varscan2
- CELA3A | c.751A>C p.T251P | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51582962; called by muse, mutect2, varscan2
- CHD4 | c.2671C>A p.P891T (on ENST00000357008 / NM_001363606.2; = p.P904T on NM_001273.5) | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58894804; called by muse, varscan2
- CLEC4M | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs760008267, COSV50216702; called by muse, mutect2, varscan2
- COL5A1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs375600865, COSV65664570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXorf65 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52148075; called by muse, mutect2, varscan2
- DST | c.5304C>A p.D1768E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV55009082; called by muse, mutect2, varscan2
- EIF4A2 | c.989_994del p.T330_L332delinsM | In Frame Del (DEL) | VAF 67/190 reads (35%) | catalogued as COSV56216602; called by mutect2, pindel, varscan2
- ELP6 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs931047050, COSV56132034; called by muse, mutect2, varscan2
- FANCB | c.2342A>T p.E781V | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as COSV60759499; called by muse, mutect2, varscan2
- FBN2 | c.2977C>G p.R993G | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52507505; called by muse, mutect2, varscan2
- GOLGA1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs982949183, COSV52346652; called by muse, mutect2
- HEPH | c.2594C>A p.P865Q (on ENST00000343002; = p.P598Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57962062; called by muse, mutect2, varscan2
- IGSF22 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.791); catalogued as rs759693497, COSV60033076; called by muse, mutect2, varscan2
- IGSF9B | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58064931; called by muse, mutect2, varscan2
- KIF3B | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65226915; called by muse, mutect2, varscan2
- KNTC1 | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61079722; called by muse, mutect2, varscan2
- KNTC1 | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as COSV61079725; called by muse, mutect2, varscan2
- LILRB1 | c.1981C>A p.Q661K (on ENST00000427581; = p.Q610K on NM_006669.6) | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV61117325; called by muse, mutect2, varscan2
- LRRC7 | c.2329T>A p.L777I (on ENST00000651989 / NM_001370785.2; = p.L744I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50441310; called by muse, mutect2, varscan2
- MTOR | c.5857G>T p.V1953L | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as CM154579, COSV63870213; called by muse, mutect2
- MUC5B | c.9650G>A p.G3217E | Missense Mutation (SNP) | VAF 436/945 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV71591364; called by muse, mutect2, varscan2
- NRAP | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs1214260211, COSV63489772; called by muse, mutect2, varscan2
- NSD3 | c.1010A>C p.E337A | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV57618118; called by muse, mutect2, varscan2
- OR4A16 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV59042565, COSV59042689; called by muse, mutect2, varscan2
- PCSK7 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs761182228, COSV54063210; called by muse, mutect2, varscan2
- PIK3R1 | c.1715delinsGCCG p.Q572delinsRR (on ENST00000521381 / NM_181523.3; = p.Q302delinsRR on NM_181504.4) | In Frame Ins (INS) | VAF 61/145 reads (42%) | catalogued as COSV57128863; called by pindel, varscan2*
- PKHD1L1 | c.7534C>A p.L2512M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65741328; called by muse, mutect2, varscan2
- PNMA1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54093221; called by muse, mutect2, varscan2
- PNPLA5 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.688); catalogued as rs780690737, COSV53374564; called by muse, mutect2, varscan2
- PRSS23 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775668009, COSV54706576; called by muse, mutect2, varscan2
- PTPRN | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 71/157 reads (45%) | catalogued as COSV55345328; called by muse, mutect2, varscan2
- RPS7 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV59232771; called by muse, mutect2, varscan2
- SLC4A1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as rs756487315, COSV52259523; called by muse, mutect2, varscan2
- SPTA1 | c.1281A>C p.Q427H | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV63751796; called by muse, mutect2
- THSD4 | c.2129G>T p.R710L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs775684732, COSV55967055, COSV55967649; called by muse, mutect2, varscan2
- TIAM1 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751890515, COSV54537698; called by muse, mutect2, varscan2
- TRAF7 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV58213903; called by muse, mutect2, varscan2
- WAS | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV64996928; called by muse, mutect2
- CTCF | c.556dup p.Q186Pfs*5 | Frame Shift Ins (INS) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- MSRB3 | c.252_254dup p.Y84_K85insN | In Frame Ins (INS) | VAF 61/156 reads (39%) | called by mutect2, pindel, varscan2
- BGN | c.214C>A p.R72= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as COSV59036398; called by muse, mutect2, varscan2
- C1orf94 | c.1731G>A p.S577= (on ENST00000488417 / NM_001134734.2; = p.S387= on NM_032884.5) | Silent (SNP) | VAF 115/244 reads (47%) | catalogued as rs143754417; called by muse, mutect2, varscan2
- CTNND2 | c.2598G>A p.A866= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs779737422, COSV58881028; called by muse, mutect2, varscan2
- FNDC1 | c.4374G>A p.T1458= | Silent (SNP) | VAF 141/354 reads (40%) | catalogued as rs770147936, COSV51930869; called by muse, mutect2, varscan2
- HELZ | c.2859G>A p.V953= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV62377709; called by muse, mutect2, varscan2
- INPP5B | c.2649C>G p.A883= (on ENST00000373023; = p.A803= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 85/206 reads (41%) | catalogued as COSV65960411; called by muse, mutect2, varscan2
- JPH2 | c.972C>T p.H324= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs757316297, COSV65902933, COSV65905706; ClinVar: likely benign; called by muse, mutect2, varscan2
- L1CAM | c.3660C>T p.N1220= | Silent (SNP) | VAF 72/177 reads (41%) | catalogued as rs782388610, COSV62827745; called by muse, mutect2, varscan2
- MACROH2A1 | c.543C>T p.D181= (on ENST00000510038; = p.D180= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs781075052, COSV56894429; called by muse, mutect2, varscan2
- MAP3K15 | c.1230G>T p.L410= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV58828571; called by muse, mutect2, varscan2
- NR2F6 | c.1188C>T p.F396= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as COSV52243425; called by muse, mutect2, varscan2
- NUDT22 | c.96C>T p.R32= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1250282912, COSV54173055; called by muse, mutect2, varscan2
- PDZD4 | c.834C>T p.S278= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs782308126, COSV51245360; called by muse, mutect2, varscan2
- SSTR4 | c.828C>T p.Y276= | Silent (SNP) | VAF 305/682 reads (45%) | catalogued as rs755279669, COSV54796877; called by muse, mutect2, varscan2
- TMPRSS5 | c.1038C>A p.G346= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV55423341; called by muse, mutect2, varscan2
- TTN | c.16143G>A p.K5381= (on ENST00000591111; = p.K4454= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV59994613; called by muse, mutect2, varscan2
- TUBAL3 | c.762C>T p.P254= | Silent (SNP) | VAF 136/304 reads (45%) | catalogued as rs782268673, COSV66814164; called by muse, mutect2, varscan2
- CUX1 | chr7:101816066 G>A | 5'Flank (SNP) | VAF 53/152 reads (35%) | catalogued as COSV52896673; called by muse, mutect2, varscan2
